Gene-level copy-number profile of tumor specimen TCGA-97-8552-01A from TCGA case TCGA-97-8552, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Bronchiolo-alveolar carcinoma, non-mucinous; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage I; Age at diagnosis: 55.7 years (20,331 days).
Specimen TCGA-97-8552-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.8546b5dc-43ce-486d-93cf-2c16b83c9d4e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-97-8552-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/922556a0-fa16-4a80-b772-abac721a5c16

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,767; copy number 2: 40,162; copy number 3: 9,858; copy number 4: 2,617; copy number 5: 416.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-97-8552-01A-11D-2389-01): tumor purity 0.27, ploidy 3.6, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 416 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:46,894,624–47,188,844, 1 gene, copy number 5 (within-gene range 2–5): EYA2.
- chr20:47,071,865–64,313,132, 415 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,767. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
